Gene-level copy-number profile of tumor specimen BLGSP-71-06-00078-01B from CGCI case BLGSP-71-06-00078, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS.
Specimen BLGSP-71-06-00078-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 03653470-6904-43ce-ab89-2e75c7b96f8f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00078-99A (granulocytes); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,796 have no estimate.
https://portal.gdc.cancer.gov/files/fef5c81d-d991-44a9-b73d-ef178e02b39d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 5,961; copy number 2: 43,624; copy number 3: 7,898; copy number 4: 1,157; copy number 5: 65; copy number 6: 26; copy number 7: 18; copy number 8: 13; copy number 9: 8; copy number 10: 17; copy number 11: 3; copy number 16: 1; copy number 42: 1.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,245,596, 34 genes (within-gene range 0–6): IGKC, IGKJ5, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV2-28, IGKV2-29, IGKV2-30.
- chr9:65,282,101–65,285,209, 1 gene: FOXD4L5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 152 genes in 40 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:121,314,947–121,315,055, 1 gene, copy number 9: AC243994.1.
- chr1:198,597,724–198,757,476, 4 genes, copy number 5–6: AL157402.1, PTPRC, AL157402.2, PEBP1P3.
- chr2:55,435,156–55,435,622, 1 gene, copy number 5: BTF3P5.
- chr2:87,454,781–87,767,359, 2 genes, copy number 5 (within-gene range 2–5): CYTOR, AC133644.2.
- chr2:87,565,828–87,566,764, 1 gene, copy number 5: PAFAH1B1P1.
- chr2:89,252,211–89,887,247, 15 genes, copy number 5–6: IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA, IGKV2D-40, IGKV1D-39, IGKV1D-37, IGKV2D-36.
- chr2:89,936,859–90,005,629, 7 genes, copy number 5: IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24.
- chr2:112,368,369–112,434,488, 1 gene, copy number 5: RGPD8.
- chr2:197,250,858–197,312,740, 3 genes, copy number 5 (within-gene range 4–5): ANKRD44-IT1, ATP5MC2P3, AC010746.2.
- chr4:39,546,336–39,666,879, 4 genes, copy number 5 (within-gene range 4–5): SMIM14, AC108471.3, RNU7-11P, AC108471.2.
- chr6:32,628,179–32,668,383, 3 genes, copy number 5: HLA-DQA1, HLA-DQB1, HLA-DQB1-AS1.
- chr6:60,281,444–60,546,660, 1 gene, copy number 5: AC244258.1.
- chr6:89,926,528–90,296,908, 1 gene, copy number 5 (within-gene range 4–5): BACH2.
- chr6:90,073,051–90,363,912, 4 genes, copy number 5: AL158136.1, AL117342.1, AL132996.1, MIR4464.
- chr7:63,348,861–63,359,306, 4 genes, copy number 5 (within-gene range 4–5): AC006455.5, AC006455.2, AC006455.3, AC006455.4.
- chr7:63,449,819–63,456,687, 1 gene, copy number 9: ZNF734P.
- chr7:73,005,541–73,207,283, 16 genes, copy number 10 (within-gene range 2–10): PMS2P7, Y_RNA, SPDYE8, PMS2P8, Y_RNA, AC211476.5, AC211476.3, SPDYE11, AC211476.4, Y_RNA, SPDYE9, PMS2P6, Y_RNA, SPDYE10P, GTF2IP4, PHBP5.
- chr7:74,773,962–74,789,376, 1 gene, copy number 6: NCF1.
- chr8:95,133,785–95,156,685, 1 gene, copy number 5: PLEKHF2.
- chr9:64,637,845–64,811,429, 3 genes, copy number 7–16: AL445665.1, BMS1P11, BNIP3P4.
- chr9:64,878,790–65,230,861, 5 genes, copy number 5–10: AC125634.1, RNU6-1293P, BMS1P12, AL512605.1, AL512605.2.
- chr10:61,901,684–62,096,944, 1 gene, copy number 5: ARID5B.
- chr11:48,014,406–48,015,855, 1 gene, copy number 5: PTPRJ-AS1.
- chr11:102,347,211–102,470,384, 3 genes, copy number 5 (within-gene range 4–5): BIRC2, TMEM123, AP001830.1.
- chr12:123,458,088–123,473,154, 1 gene, copy number 5 (within-gene range 3–5): SNRNP35.
- chr13:46,334,681–46,438,190, 3 genes, copy number 5 (within-gene range 4–5): RUBCNL, RNU2-6P, RNU6-68P.
- chr13:46,553,168–46,753,040, 1 gene, copy number 5 (within-gene range 4–5): LRCH1.
- chr14:18,333,726–18,650,966, 17 genes, copy number 7: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11.
- chr14:18,709,478–19,003,752, 9 genes, copy number 8–11: NF1P10, NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2, POTEM, AL929601.3, RNU6-1239P.
- chr14:106,810,442–106,879,812, 11 genes, copy number 8: IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr15:20,516,252–20,520,627, 1 gene, copy number 5: AC023310.1.
- chr15:43,599,563–43,618,800, 1 gene, copy number 6 (within-gene range 3–6): STRC.
- chr15:43,614,208–43,632,283, 1 gene, copy number 6 (within-gene range 3–6): AC011330.3.
- chr15:43,663,654–43,684,339, 1 gene, copy number 9 (within-gene range 3–9): AC011330.1.
- chr21:9,068,361–9,129,752, 3 genes, copy number 6: TEKT4P2, SOWAHCP2, CR392039.2.
- chr21:10,397,644–13,120,807, 13 genes, copy number 5: AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr21:43,414,483–43,427,131, 1 gene, copy number 5: SIK1.
- chr21:43,461,960–43,479,534, 1 gene, copy number 42 (within-gene range 4–42): LINC00313.
- chr21:44,133,610–44,210,114, 1 gene, copy number 6 (within-gene range 3–6): GATD3A.
- chr21:44,172,169–44,207,399, 3 genes, copy number 6: AP001056.2, AP001056.1, AP001057.1.

Autosomal genes at a single copy (total copy number 1): 3,119. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
